Somatic mutation profile of tumor specimen TCGA-AN-A0FX-01A (aliquot TCGA-AN-A0FX-01A-11W-A050-09) from TCGA case TCGA-AN-A0FX, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 52.9 years (19,309 days).
Specimen TCGA-AN-A0FX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2023b890-0d27-4abf-973b-510a62128820.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A0FX-10A (Blood Derived Normal), aliquot TCGA-AN-A0FX-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d0f4e7d-50de-4ad2-82bc-20d0744b644d

The open-access MAF lists 97 somatic variants for this specimen: 77 protein-altering or splice-affecting, 16 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 16, Frame Shift Del 5, Nonsense Mutation 3, Intron 2, In Frame Del 2, Splice Site 2, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1E | c.2104G>A p.A702T | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs12131800, COSV62415002; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ETFB | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs104894677, CM940380, COSV100164354, COSV100164357; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 65/155 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGK | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 44/358 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs989006017, COSV62595781; called by muse, mutect2, varscan2
- AKAP13 | c.1220G>A p.C407Y | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs768166553, COSV63467925; called by muse, mutect2, varscan2
- AKAP4 | c.1453G>T p.D485Y | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV62075371; called by muse, mutect2, varscan2
- AQP4 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.121); catalogued as COSV67219307; called by muse, mutect2, varscan2
- ATP1A4 | c.1847G>T p.G616V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63628244, COSV63628270; called by muse, mutect2
- ATP2B1 | c.3007A>G p.I1003V | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV53812142; called by muse, mutect2, varscan2
- ATP5F1C | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV59622819; called by muse, mutect2, varscan2
- CNTLN | c.813G>C p.L271F | Missense Mutation (SNP) | VAF 139/215 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV52094160; called by muse, mutect2, varscan2
- CRYBA1 | c.297G>A p.W99* | Nonsense Mutation (SNP) | VAF 6/104 reads (6%) | catalogued as COSV99837024; called by muse, mutect2
- CWH43 | c.1685C>G p.A562G | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1224184725, COSV56943192; called by muse, mutect2, varscan2
- DHX32 | c.1867G>C p.G623R | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52938098, COSV52943042; called by muse, mutect2, varscan2
- DNAJC9 | c.680G>C p.R227P | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs148829608, COSV54354303; called by muse, mutect2, varscan2
- ERBB3 | c.1132G>C p.A378P | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT tolerated (0.98); PolyPhen benign (0.038); catalogued as COSV57261816; called by muse, mutect2, varscan2
- FAM135A | c.3925C>T p.Q1309* (on ENST00000370479 / NM_001351599.1; = p.Q1096* on NM_020819.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV52057978; called by muse, mutect2, varscan2
- FLNC | c.5723del p.D1908Afs*45 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as COSV57963466; called by mutect2, pindel, varscan2
- GIMAP7 | c.23C>A p.S8Y | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV57960429; called by muse, mutect2, varscan2
- GOLGB1 | c.5190G>T p.R1730S | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.045); catalogued as rs140861121; called by muse, mutect2, varscan2
- GPNMB | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51700600; called by muse, mutect2, varscan2
- HERC2 | c.1663C>T p.H555Y | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.307); catalogued as COSV99874237; called by muse, mutect2, varscan2
- INPPL1 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | catalogued as COSV53358883; called by muse, mutect2, varscan2
- INSIG2 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as rs758358013, COSV55523539; called by muse, mutect2, varscan2
- KIAA1549 | c.208C>G p.H70D | Missense Mutation (SNP) | VAF 73/141 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); catalogued as COSV54326145; called by muse, mutect2, varscan2
- KRIT1 | c.1631A>T p.Y544F | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV60670174; called by muse, mutect2, varscan2
- LGR6 | c.2411C>T p.T804M (on ENST00000367278 / NM_001017403.1; = p.T752M on NM_021636.3) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs140358092; called by muse, mutect2, varscan2
- LIF | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs753939297, COSV50777222; called by muse, mutect2, varscan2
- LRRC36 | c.476A>T p.E159V | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV52081812; called by muse, varscan2
- MAP2K3 | c.466G>T p.D156Y (on ENST00000342679 / NM_145109.3; = p.D127Y on NM_002756.4) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as rs748513234, COSV57576469; called by muse, mutect2, varscan2
- MATN2 | c.327C>G p.F109L | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99646423; called by muse, mutect2
- MPV17L | c.485C>T p.T162I (on ENST00000396385 / NM_001128423.2; = p.H138= on NM_173803.4) | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV55009062; called by muse, mutect2, varscan2
- MTM1 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.154); catalogued as COSV60337282; called by mutect2, varscan2
- NCMAP | c.38T>G p.F13C | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.789); catalogued as COSV65557520; called by muse, mutect2, varscan2
- NFE2L3 | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as rs746360893, COSV50236984; called by muse, mutect2, varscan2
- NLGN4X | c.2300C>T p.S767L | Missense Mutation (SNP) | VAF 134/237 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as rs762832258, COSV52019787; called by muse, mutect2, varscan2
- NTAQ1 | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV99783644; called by muse, mutect2
- OR1J2 | c.917G>T p.S306I | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.211); catalogued as COSV58945056; called by muse, mutect2, varscan2
- PARP8 | c.2355A>T p.L785F | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99891710; called by muse, mutect2
- PCDHA9 | c.1985C>T p.T662M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.921); catalogued as rs572249977, COSV65324558; called by muse, mutect2, varscan2
- PCNT | c.3973G>C p.E1325Q | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0.01); catalogued as COSV64032471; called by muse, mutect2, varscan2
- PSD2 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs778796105, COSV51208740; called by muse, mutect2, varscan2
- RASGRF1 | c.384C>A p.S128R | Missense Mutation (SNP) | VAF 75/155 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.386); catalogued as COSV69182695; called by muse, mutect2, varscan2
- RPL7 | c.11T>G p.V4G | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV53584161; called by muse, mutect2, varscan2
- RRNAD1 | c.1314T>G p.H438Q | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV63928698, COSV63929381; called by muse, mutect2, varscan2
- RTL9 | c.170A>G p.D57G | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV71826225; called by muse, mutect2, varscan2
- SEMA5A | c.502A>C p.N168H | Missense Mutation (SNP) | VAF 124/270 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66803868; called by muse, mutect2, varscan2
- SMC1A | c.1142A>T p.E381V | Missense Mutation (SNP) | VAF 18/550 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.377); catalogued as COSV100447419; called by muse, mutect2
- SPPL3 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.726); catalogued as rs1377944618, COSV62234088; called by muse, mutect2, varscan2
- ST3GAL3 | c.731C>T p.A244V (on ENST00000361392 / NM_174964.4; = p.A229V on NM_006279.5) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.936); catalogued as rs1267241953, COSV53519596; called by muse, varscan2
- STOM | c.863G>C p.G288A | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs932872444, COSV54419212; called by muse, mutect2, varscan2
- TAAR5 | c.661A>C p.K221Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV57799777; called by muse, varscan2
- TEP1 | c.5926G>T p.A1976S | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as rs1248740822, COSV52998899; called by muse, mutect2, varscan2
- TMEM207 | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); catalogued as COSV61562205; called by muse, mutect2, varscan2
- TMEM9 | c.368C>G p.T123S | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.298); catalogued as COSV66244143; called by muse, mutect2, varscan2
- TTC38 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66844981; called by muse, mutect2, varscan2
- UBR4 | c.737G>C p.S246T | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.051); catalogued as COSV64398023; called by muse, mutect2, varscan2
- VAMP3 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1393590862, COSV50012876; called by muse, mutect2, varscan2
- XPO7 | c.3200G>A p.R1067Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV53017156; called by muse, mutect2, varscan2
- YIPF1 | c.847G>T p.A283S | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.095); catalogued as COSV50779057; called by muse, mutect2, varscan2
- ZFC3H1 | c.384T>G p.S128R | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100350322; called by mutect2, varscan2
- ZFHX3 | c.6956G>A p.R2319K | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51737739, COSV99212991; called by muse, mutect2
- ZKSCAN7 | c.2018G>A p.S673N | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.227); catalogued as COSV56274290; called by muse, mutect2, varscan2
- ZNF133 | c.1418G>T p.R473L (on ENST00000316358 / NM_001352454.2; = p.R472L on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/148 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100315454; called by muse, varscan2
- ZNF141 | c.733C>G p.H245D | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV53661376; called by muse, mutect2, varscan2
- ZNF823 | c.1443T>A p.S481R (on ENST00000341191 / NM_001297610.2; = p.S437R on NM_017507.2) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.885); catalogued as COSV100362503; called by muse, mutect2, varscan2
- ZRANB1 | c.1294C>G p.L432V | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV62843858; called by muse, mutect2, varscan2
- AP2M1 | c.120_139del p.Q41Hfs*12 | Frame Shift Del (DEL) | VAF 65/114 reads (57%) | called by mutect2, pindel, varscan2
- C5orf51 | c.31_39del p.R11_E13del | In Frame Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- CREBBP | c.1664del p.L555Rfs*7 | Frame Shift Del (DEL) | VAF 23/194 reads (12%) | called by mutect2, pindel, varscan2
- CTTNBP2 | c.2768_2778+28del p.X923_splice | Splice Site (DEL) | VAF 28/150 reads (19%) | called by mutect2, pindel
- IER5 | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by mutect2, varscan2
- ITPR1 | c.6401_6402del p.V2134Gfs*3 (on ENST00000354582; = p.V2079Gfs*3 on NM_002222.7) | Frame Shift Del (DEL) | VAF 203/419 reads (48%) | called by mutect2, pindel, varscan2
- KLHDC1 | c.712_733del p.I238Qfs*9 | Frame Shift Del (DEL) | VAF 26/82 reads (32%) | called by mutect2, pindel, varscan2
- LIPG | c.1160T>G p.V387G | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); called by mutect2, varscan2
- SLC12A1 | c.547_552+9del p.X183_splice | Splice Site (DEL) | VAF 17/209 reads (8%) | called by mutect2, pindel
- TANGO6 | c.1635_1637del p.G546del | In Frame Del (DEL) | VAF 39/126 reads (31%) | called by pindel, varscan2
- AARS2 | c.1065T>C p.R355= | Silent (SNP) | VAF 50/185 reads (27%) | catalogued as COSV55117263; called by muse, mutect2, varscan2
- ASCC3 | c.4023G>A p.T1341= | Silent (SNP) | VAF 48/90 reads (53%) | catalogued as rs140450400; called by muse, mutect2, varscan2
- ASH1L | c.2949C>A p.I983= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV100853449; called by muse, mutect2
- CDC25C | c.1333C>T p.L445= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as COSV60401039; called by muse, mutect2, varscan2
- CIC | c.1542C>A p.P514= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs1052483785, COSV50654781, COSV99359723; called by muse, mutect2, varscan2
- CSPP1 | c.240T>C p.D80= (on ENST00000676605; = p.D39= on NM_024790.6) | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as COSV51591598; called by muse, mutect2, varscan2
- ESYT2 | c.2511A>C p.G837= (on ENST00000613624; = p.G761= on NM_020728.3) | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV51755655; called by muse, mutect2, varscan2
- FAM47C | c.15G>A p.R5= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV63729897; called by muse, varscan2
- FLG2 | c.918A>G p.Q306= | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as COSV66172314; called by muse, varscan2
- GALNT6 | c.750C>T p.I250= | Silent (SNP) | VAF 41/80 reads (51%) | catalogued as COSV100695573, COSV62543621; called by muse, varscan2
- GTPBP4 | c.327T>C p.V109= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV100672696; called by muse, mutect2
- LAT2 | c.183C>T p.V61= | Silent (SNP) | VAF 88/99 reads (89%) | catalogued as rs782154494, COSV99305825; called by muse, mutect2, varscan2
- NPC1L1 | c.1339C>T p.L447= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV56929629; called by muse, varscan2
- OR2G2 | c.585C>A p.T195= | Silent (SNP) | VAF 91/296 reads (31%) | catalogued as COSV60742136; called by muse, mutect2, varscan2
- SMC2 | c.1914A>G p.K638= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV53963887; called by muse, mutect2, varscan2
- TECPR1 | c.1392C>G p.A464= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV101130514; called by mutect2, varscan2
- AC092718.9 | chr16:81149812 C>G | 5'Flank (SNP) | VAF 15/65 reads (23%) | catalogued as rs772338955; called by muse, mutect2, varscan2
- COLQ | c.107-8911A>G | Intron (SNP) | VAF 22/139 reads (16%) | catalogued as COSV67525812; called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142671199 C>T | 3'Flank (SNP) | VAF 34/125 reads (27%) | called by muse, mutect2, varscan2
- RMDN2 | c.452+21548A>G | Intron (SNP) | VAF 12/107 reads (11%) | catalogued as COSV52228726; called by muse, mutect2, varscan2
